Somatic mutation profile of tumor specimen TCGA-F5-6810-01A (aliquot TCGA-F5-6810-01A-11D-1826-10) from TCGA case TCGA-F5-6810, project TCGA-READ (Rectum Adenocarcinoma).
Specimen TCGA-F5-6810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c6ea2be-5feb-4c21-81eb-9df8b0a5e106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6810-10A (Blood Derived Normal), aliquot TCGA-F5-6810-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ffb50d3-a6c1-431f-b7e5-dc6fe830d81c

The open-access MAF lists 136 somatic variants for this specimen: 98 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 35, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 2, 3'UTR 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 85/101 reads (84%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV63663706; called by muse, mutect2, varscan2
- ADGRL2 | c.3659C>G p.A1220G (on ENST00000370717 / NM_001366005.1; = p.A1164G on NM_012302.4) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV54667286; called by muse, mutect2, varscan2
- AFP | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.795); catalogued as COSV99890117; called by muse, mutect2, varscan2
- ANK1 | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1321444548, COSV55877451; called by muse, mutect2, varscan2
- AP3B1 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV54892819, COSV54895991; called by muse, mutect2, varscan2
- ARFGEF2 | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771896640, COSV100904328; called by muse, mutect2, varscan2
- ARPP21 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.548); catalogued as COSV51800341, COSV51805004; called by muse, mutect2, varscan2
- ATP2C2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1010492688, COSV52294819; called by muse, mutect2, varscan2
- B4GALT3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs775570899, COSV60527210; called by muse, mutect2, varscan2
- BICD1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as COSV55690448, COSV99862628; called by muse, mutect2, varscan2
- C2orf88 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.785); catalogued as COSV100502828; called by muse, mutect2, varscan2
- CACNA1E | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs757105337, COSV62395307; called by muse, mutect2, varscan2
- CACNA1E | c.6088A>G p.N2030D (on ENST00000367573 / NM_001205293.3; = p.N1987D on NM_000721.4) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV62395314; called by muse, mutect2, varscan2
- CAND1 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV101598280, COSV73338589; called by muse, mutect2, varscan2
- CBLB | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51431000; called by muse, mutect2, varscan2
- CCDC114 | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV59556664, COSV59556945; called by muse, mutect2, varscan2
- CNGB1 | c.2605G>A p.V869I | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs61735107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT8 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 115/246 reads (47%) | catalogued as COSV99597205; called by muse, mutect2, varscan2
- COL22A1 | c.2032-2A>T p.X678_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100279029, COSV57334952; called by muse, mutect2, varscan2
- CTR9 | c.2616G>C p.K872N | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100797208, COSV63728990; called by muse, mutect2, varscan2
- DGKI | c.2905A>G p.T969A | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV99935524; called by muse, mutect2, varscan2
- EDN2 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV101006347; called by muse, mutect2, varscan2
- FAM184A | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV58854474; called by muse, mutect2, varscan2
- FARS2 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV99213058; called by muse, mutect2, varscan2
- FAT4 | c.4235A>T p.D1412V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101272362; called by muse, mutect2, varscan2
- FBXO15 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs549233857, COSV54042674; called by muse, mutect2, varscan2
- FOLH1 | c.2063+1G>A p.X688_splice | Splice Site (SNP) | VAF 39/273 reads (14%) | catalogued as COSV99922918, COSV99923424; called by muse, mutect2, varscan2
- GABRR3 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.035); catalogued as COSV101512303; called by muse, mutect2, varscan2
- GLB1L2 | c.845G>T p.W282L | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1432969601, COSV100335404; called by muse, mutect2, varscan2
- GTF3C4 | c.2433A>C p.Q811H | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100936033; called by muse, mutect2, varscan2
- H3-4 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1431559822, COSV64210790; called by muse, mutect2, varscan2
- HDC | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51080336, COSV99984136; called by muse, mutect2, varscan2
- HMX2 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100378790; called by muse, mutect2, varscan2
- HPCAL1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV57146150; called by muse, mutect2, varscan2
- HRH1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs201947424, COSV67955106; called by muse, mutect2, varscan2
- HYAL1 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs782616691, COSV56498920; called by muse, mutect2, varscan2
- IGFN1 | c.1757G>T p.G586V (on ENST00000295591 / NM_001367841.1; = p.G3043V on NM_001164586.2) | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55172744, COSV55185333; called by muse, mutect2, varscan2
- INTS1 | c.6433C>A p.P2145T | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV101248046; called by muse, mutect2, varscan2
- ITPRID1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs767533614, COSV60074961; called by muse, mutect2, varscan2
- KIAA1958 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61723817; called by muse, mutect2, varscan2
- KIF26B | c.3893T>C p.F1298S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV100832740; called by muse, mutect2, varscan2
- KIF26B | c.3894C>A p.F1298L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV100832745, COSV63639236; called by muse, mutect2, varscan2
- KIRREL2 | c.522+1G>A p.X174_splice | Splice Site (SNP) | VAF 33/161 reads (20%) | catalogued as COSV52876496; called by muse, mutect2, varscan2
- KMT5B | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV100430292; called by muse, mutect2, varscan2
- LARP1 | c.856G>A p.G286R (on ENST00000518297 / NM_033551.3; = p.G209R on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1272104521, COSV60424974; called by muse, mutect2, varscan2
- LAT | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs760777156, COSV100611493; called by muse, mutect2, varscan2
- LRRK2 | c.5203C>T p.R1735* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as rs1381739913, COSV100110597; called by muse, mutect2, varscan2
- MDN1 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101020650, COSV65517441; called by muse, mutect2, varscan2
- MEN1 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as CM074348, COSV53643427, COSV53647685; called by muse, mutect2, varscan2
- MFSD11 | c.438C>G p.S146R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100334014; called by muse, mutect2, varscan2
- MOS | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.588); catalogued as COSV100322875; called by muse, mutect2, varscan2
- MTHFSD | c.313G>C p.A105P (on ENST00000360900 / NM_001159377.2; = p.A104P on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/200 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59803299; called by muse, mutect2, varscan2
- MYF5 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57356615; called by muse, mutect2, varscan2
- NFASC | c.2711C>T p.T904M (on ENST00000339876 / NM_001378329.1; = p.T1007M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1217561752, COSV100364298, COSV58360528; called by muse, mutect2, varscan2
- NRXN2 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as COSV99634793; called by muse, mutect2, varscan2
- OR2M5 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63546290; called by muse, mutect2, varscan2
- OR52L1 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV59986537; called by muse, mutect2, varscan2
- OR5R1 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.082); catalogued as COSV100393494; called by muse, mutect2, varscan2
- PCDH7 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62338956; called by muse, mutect2, varscan2
- PCDHA8 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100969746; called by muse, mutect2, varscan2
- PGPEP1L | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as rs768652203, COSV66709263; called by mutect2, varscan2
- PIKFYVE | c.3383T>A p.L1128* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs1217680982, COSV100010968; called by muse, mutect2, varscan2
- PIM3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs775149860, COSV100638429; called by muse, mutect2, varscan2
- PSG1 | c.1172T>A p.L391H | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV54949469; called by muse, mutect2, varscan2
- RASA1 | c.2744T>G p.F915C | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99170026; called by muse, mutect2, varscan2
- REC114 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779792470, COSV58524592; called by muse, mutect2, varscan2
- RHEBL1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1302826741, COSV56505196, COSV99988020; called by muse, mutect2, varscan2
- RYR2 | c.12878C>G p.T4293S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100771290; called by muse, mutect2, varscan2
- RYR3 | c.11312A>T p.D3771V (on ENST00000389232; = p.D3772V on NM_001036.6) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213086; called by muse, mutect2, varscan2
- SIGLEC1 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs750548827, COSV52459387; called by muse, mutect2, varscan2
- SLC12A2 | c.2240T>A p.I747N | Missense Mutation (SNP) | VAF 117/246 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV99321221; called by muse, mutect2, varscan2
- SLC15A2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99815604; called by muse, mutect2, varscan2
- SLC28A3 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV66153192; called by muse, mutect2, varscan2
- SLCO1A2 | c.1243G>T p.V415F | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56602267; called by muse, mutect2, varscan2
- SMARCD3 | c.1200C>G p.N400K (on ENST00000262188 / NM_001003801.2; = p.N387K on NM_003078.4) | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV50390914; called by muse, mutect2, varscan2
- SORCS1 | c.2584G>A p.V862M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs759089178, COSV53870768; called by muse, mutect2, varscan2
- SP110 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.312); catalogued as COSV51251212; called by muse, mutect2, varscan2
- SQLE | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV56280836; called by muse, mutect2, varscan2
- STIMATE | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs549819429, COSV100753785, COSV61890629; called by muse, mutect2, varscan2
- SYNGAP1 | c.3370G>A p.G1124R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs748702892, COSV99538568; called by muse, mutect2, varscan2
- TCF7L2 | c.1250G>A p.W417* (on ENST00000355995 / NM_001367943.1; = p.W394* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 30/48 reads (63%) | catalogued as COSV53340917; called by muse, mutect2, varscan2
- TEX15 | c.5416T>A p.F1806I (on ENST00000256246; = p.F2189I on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821554; called by muse, mutect2, varscan2
- TRPV4 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780102339, COSV55681445; called by muse, mutect2, varscan2
- TSNAXIP1 | c.738C>A p.N246K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54649815; called by muse, mutect2, varscan2
- USF3 | c.5222G>A p.G1741E | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57072816; called by muse, mutect2, varscan2
- USH2A | c.13096G>A p.A4366T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs765764429, COSV100237529; called by muse, mutect2, varscan2
- UTP4 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 162/257 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100077034; called by muse, mutect2, varscan2
- VAT1L | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs375801874, COSV56825534, COSV56829330; called by muse, mutect2, varscan2
- ZFP82 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101089140; called by muse, mutect2, varscan2
- ZNF425 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100955503; called by muse, mutect2
- ZNF518B | c.2975T>C p.L992P | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100456767; called by muse, mutect2, varscan2
- ZNF790 | c.1544T>A p.F515Y | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100764853; called by muse, mutect2, varscan2
- CNOT1 | c.1585-2dup p.X529_splice | Splice Site (INS) | VAF 33/138 reads (24%) | called by mutect2, pindel, varscan2
- GNGT1 | c.188_201del p.P63Qfs*40 | Frame Shift Del (DEL) | VAF 26/227 reads (11%) | called by mutect2, pindel
- KIAA1210 | c.3303dup p.A1102Cfs*9 | Frame Shift Ins (INS) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- MRC1 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 177/359 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TP53 | c.631_632del p.T211Ffs*4 | Frame Shift Del (DEL) | VAF 46/92 reads (50%) | called by pindel, varscan2
- ADAMTS19 | c.2712T>C p.T904= | Silent (SNP) | VAF 78/147 reads (53%) | catalogued as rs1180590628, COSV99179298; called by muse, mutect2, varscan2
- ADCY9 | c.114C>A p.S38= | Silent (SNP) | VAF 45/304 reads (15%) | catalogued as COSV53575337; called by muse, mutect2, varscan2
- AKAP8 | c.612C>T p.F204= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99512008; called by muse, mutect2, varscan2
- AP3B2 | c.3207C>T p.S1069= (on ENST00000261722; = p.S1063= on NM_004644.5) | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as rs540715932, COSV55607437; called by muse, mutect2, varscan2
- ASB4 | c.742C>A p.R248= | Silent (SNP) | VAF 60/183 reads (33%) | catalogued as rs1433650027, COSV100367209; called by muse, mutect2, varscan2
- ASXL2 | c.1620C>A p.P540= | Silent (SNP) | VAF 170/319 reads (53%) | catalogued as COSV55458970; called by muse, mutect2, varscan2
- B4GAT1 | c.360G>C p.L120= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100240309; called by muse, mutect2, varscan2
- BICC1 | c.1653T>C p.P551= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99570673; called by muse, mutect2, varscan2
- CCDC39 | c.1833G>A p.A611= | Silent (SNP) | VAF 200/594 reads (34%) | catalogued as rs371164022; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP61 | c.3615G>A p.E1205= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV99845459; called by muse, mutect2, varscan2
- COL15A1 | c.3957C>T p.P1319= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV100897829; called by muse, mutect2, varscan2
- CREBBP | c.5628C>T p.N1876= | Silent (SNP) | VAF 36/250 reads (14%) | catalogued as rs747210551, COSV99270616; called by muse, mutect2, varscan2
- CYBC1 | c.396G>A p.T132= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs754752685, COSV100027635, COSV100027796; called by muse, mutect2, varscan2
- DLGAP2 | c.1890G>A p.T630= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as rs146676417, COSV70098382; called by muse, mutect2, varscan2
- DMBT1 | c.399C>T p.T133= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV57544035; called by muse, mutect2, varscan2
- EBF3 | c.1743C>T p.N581= (on ENST00000355311 / NM_001375392.1; = p.N536= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs7092828; called by muse, mutect2, varscan2
- EDRF1 | c.2418C>G p.L806= (on ENST00000356792 / NM_001202438.2; = p.L772= on NM_015608.2) | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV100523611; called by muse, mutect2, varscan2
- EPHB2 | c.753C>T p.I251= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs368639670, COSV65866432; called by muse, mutect2, varscan2
- FCRLB | c.294C>T p.L98= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100396171, COSV100396232; called by muse, mutect2, varscan2
- FOXG1 | c.669G>A p.Q223= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as COSV100486635, COSV57396851; called by muse, mutect2, varscan2
- GLI3 | c.1431C>T p.I477= | Silent (SNP) | VAF 67/437 reads (15%) | catalogued as COSV67893906; called by muse, mutect2, varscan2
- GSPT1 | c.1020C>T p.N340= (on ENST00000420576 / NM_001130007.2; = p.N478= on NM_002094.4) | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs377596394; called by muse, mutect2, varscan2
- HIPK1 | c.1821C>A p.V607= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV100479300; called by muse, varscan2
- LDHAL6A | c.72C>T p.S24= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV99773131; called by muse, mutect2, varscan2
- LRP1 | c.1824C>T p.A608= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1304752304, COSV99676289; called by muse, mutect2, varscan2
- NEDD4 | c.1509C>T p.S503= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as rs770265553, COSV100163851; called by muse, mutect2, varscan2
- OPCML | c.615G>A p.L205= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs780936478, COSV100102623; called by muse, mutect2, varscan2
- OR5R1 | c.720C>T p.T240= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as COSV56573164; called by muse, mutect2, varscan2
- P2RX5 | c.1224C>T p.N408= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs201152395, COSV99835861; called by muse, mutect2, varscan2
- SLC12A2 | c.2241T>A p.I747= | Silent (SNP) | VAF 118/245 reads (48%) | catalogued as COSV99321223; called by muse, mutect2, varscan2
- TENM1 | c.7140T>G p.V2380= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as rs767334788, COSV100950334; called by muse, mutect2, varscan2
- TTN | c.15003C>G p.L5001= (on ENST00000591111; = p.L4074= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV100618617; called by muse, mutect2, varscan2
- TULP1 | c.648G>A p.A216= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs766865255, COSV57692511; called by muse, mutect2, varscan2
- WDR36 | c.1140T>C p.A380= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV101540809; called by muse, mutect2, varscan2
- YIPF7 | c.510T>C p.V170= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100274546; called by muse, mutect2, varscan2
- ETNK1 | c.-240_-238del | 5'UTR (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- SSPOP | n.5727C>T | RNA (SNP) | VAF 32/68 reads (47%) | catalogued as rs562038201, COSV100022664; called by muse, mutect2, varscan2
- STBD1 | c.*2dup | 3'UTR (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
